Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A22R, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A22R-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium c54.1 4/21/11

Surgical Pathology Consultation Report

Gender: F

Specimen(s) Received

1. Soft-Tissue: right internal iliac node for Q/S
2. Lymph node: Right Obturator node -QS
3. Uterus: CX Tubes and Ovaries
4. Soft Tissue: Left Proximal External iliac
5. Lymph node: Left Pelvic
6. Lymph node: Left Obturator Node

Diagnosis

1. Lymph nodes, right internal iliac:
- Negative for carcinoma (six lymph nodes)
2. Lymph nodes, right obturator:
- Negative for carcinoma (four lymph nodes)
3. Uterus, left & right fallopian tubes and ovaries:

Uterus:

ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, GRADE 3/3 (please see comment):

- extension into outer one third of myometrium
- lymphovascular space invasion is present
- uninvolved endometrium - atrophic
- leiomyomata uteri
- adenomyosis

Cervix:

Negative for malignancy

Fallopian tubes:

- No diagnostic abnormality

Ovaries:

- Serous cyst adenofibroma, left ovary

[page 2 of 4]
- Cystic mesothelial adhesion, left ovary
- Bilateral surface papillary stromal hyperplasia

4. Lymph node, left proximal external iliac:
- Negative for carcinoma (one lymph node)

5. Lymph nodes, left pelvic:
- Negative for carcinoma (three lymph nodes)

6. Lymph nodes, left obturator:
- Negative for carcinoma (four lymph nodes)

Synoptic Data

Specimen Type (s):	Hysterectomy, Total Hysterectomy, Left ovary, Right ovary, Left fallopian tube, Right fallopian tube
Other Organs Present:	Lymph nodes
Histologic Type:	Endometrioid adenocarcinoma, not otherwise characterized
Histologic Grade:	G3: More than 50% nonsquamous solid growth
Myometrial Invasion:	Outer third
Cervix Involvement:	None
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Present
Nodal Involvement:	None
Margins:	Uninvolved by invasive carcinoma
Pathologic Staging (pTNM):	pT1c (IC): Tumor invades one-half or more of the myometrium
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 18 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	pMX: Distant metastasis cannot be assessed

Comment

This endometrioid adenocarcinoma architecturally grade II/III however it has high grade nuclear atypia (grade III). Also there is focal area of P53 positivity in the area with high-grade nuclear atypia identified.

Electronically

verified bv:

Gross Description

1. The specimen is labeled with the patient's name and as "right internal iliac node". It consists of a piece of fatty tissue measuring 5 x 1.5 x 2.0 cm. Multiple nodes identified, the largest of which

[page 3 of 4]
measures 3 x 1.5 x 1.5 cm. Intraoperative consultation performed on a frozen by quick section. The nodes are submitted in toto.

1A-1C frozen section nodes

1D largest node bisected

2. The specimen is labeled with the patient's name and as "right obturator node". It consists of multiple lymph nodes the largest of which measures 1.7 x 0.7 x 0.5 cm. Intraoperative consultation performed on a frozen by quick section.

2A-2B frozen section nodes in toto

3. The specimen is labeled with the patient's name and as "uterus cervix tubes and ovaries". It consists of a uterus with bilateral adnexa weighing 159 g and measuring 9.8 SI x 5.6 ML x 5 APcm. The cervix measures 4.6 cm in diameter and the slit os measures 1.2 cm in length. The right ovary measures 2.5 x 1.3 x 0.8 cm on the right fallopian tube measures 5.4 x 0.5 cm. The left ovary measures 2.6 x 1.7 x 1.2 cm and the left fallopian tube measures 5 x 0.6 cm.

The serosal surface of the uterus is smooth and grossly unremarkable. The exocervix is slightly congested partly. The cervical canal appears normal. A papillary polypoid partly friable white lesion occupies the posterior endometrium, fundus and primarily the right aspect. This lesion measures 3.7 SI x 3.5 ML x 1.7 APcm. The myometrium is 0.9cm thick. Two white fibroids with whorl like appearance identified as intramural in the anterior aspect measuring 1.0 to 1.8 cm in diameter.

The right ovary is smooth on the outer surface and on sectioning it is fibrous and unremarkable. The right fallopian tube is unremarkable and the other surface and patent on cut surface. The left ovary show some tiny parovarian cyst measuring 0.1 cm in diameter on the surface. On sectioning 1 follicular cysts measuring 0.9 x 0.6 x 0.2 cm is identified. The left fallopian tube is unremarkable. Representative sections submitted.

3A left ovary and left fallopian tube

3B right ovary and right tube

3C EMC tumor

3D-3F right ovary

3G-3I right fallopian tube

3J-3L left ovary

3M-3N left fallopian tube

3O-3P anterior aspect cervix, cervical canal, lower uterine segment

3Q anterior aspect endomyometrium with polypoid tumor

3R anterior aspect endomyometrium with polypoid tumor, fibroid

3S-3T posterior aspect cervix, cervical canal, lower uterine segment

3V-3X posterior aspect endomyometrium

3Y fundus, upper endomyometrium

3Z-3AG remaining polypoid lesion

4. The specimen container, labeled with the patient's name and as "left proximal external iliac", contains a piece of fibrofatty tissue and a node measuring respectively 1.4 x 0.6 x 0.1 and 2 x 1 x 0.5 cm, received in 10% NBF. The node is submitted in toto.

4A bisected node

5. The specimen container, labeled with the patient's name and as "left pelvic", contains a piece of fibrofatty tissue measuring 3.5 x 2 x 1.5 cm, received in 10% NBF. This contains 3 lymph node measuring 0.4 x 0.4 x 0.2 cm to 0.8 x 0.5 x 0.4 cm. The nodes are submitted in toto.

5A 1 node bisected

5B one node bisected

5C one node

6. The specimen container, labeled with the patient's name and as "left obturator node", contains 2 pieces of fibrofatty tissue measuring 1.3 x 1 x 0.7 and 2.4 x 1 x 0.7 cm, received in 10% NBF.

[page 4 of 4]
4

This contains 3 lymph node measuring 0.4 x 0.4 x 0.3 cm to 0.8 x 0.4 x 0.4 cm. The specimen is submitted in toto.

6A 3 nodes

6B fat

Quick Section Diagnosis

1. Right internal iliac nodes:
Negative for carcinoma

2. Right obturator node:
Negative for carcinoma

Surgeon informed at

Source: NCI Genomic Data Commons file 4140a042-15f4-41f7-bcdc-995573f117d2 (TCGA-EO-A22R.5B97D87A-5D28-417F-A942-21775156B46C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).